Somatic mutation profile of tumor specimen TCGA-76-6656-01A (aliquot TCGA-76-6656-01A-11D-1845-08) from TCGA case TCGA-76-6656, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.4 years (24,265 days).
Specimen TCGA-76-6656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f29460fa-07ab-4633-802c-94f2afb71d7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6656-10A (Blood Derived Normal), aliquot TCGA-76-6656-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1be172c-a97d-4ca0-b355-fd7dce713853

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 24, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF35 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.101); catalogued as rs1465837045, COSV100967669; called by muse, mutect2, varscan2
- ATCAY | c.1002C>T p.S334= | Splice Region (SNP) | VAF 26/99 reads (26%) | catalogued as rs767813874, COSV56656481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC149 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765682853, COSV60882788; called by muse, mutect2, varscan2
- CCN4 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.257); catalogued as COSV51536587; called by muse, mutect2, varscan2
- CEP83 | c.1206G>C p.E402D | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100352920, COSV60411885; called by muse, mutect2
- CYP2F1 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs142026539; called by muse, mutect2, varscan2
- DNAH8 | c.7321T>G p.L2441V | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59486338; called by muse, mutect2, varscan2
- EGFR | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 635/3376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51857475; called by muse, mutect2, varscan2
- EPHA5 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56639015; called by muse, mutect2, varscan2
- FLG | c.4797C>G p.D1599E | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.35); catalogued as rs370333585; called by muse, mutect2, varscan2
- FMNL2 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV56506638; called by muse, mutect2, varscan2
- FUT3 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); catalogued as rs377154201; called by muse, mutect2, varscan2
- GABPB1 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV55018076; called by muse, mutect2, varscan2
- GSTA5 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52864187; called by muse, mutect2, varscan2
- GZMK | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs200562138, COSV50246543; called by muse, mutect2, varscan2
- HSPA12A | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as rs1423363716, COSV65024226; called by muse, mutect2, varscan2
- IGHV4-28 | c.13T>A p.W5R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs782356152; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 67/77 reads (87%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV61188598; called by muse, mutect2, varscan2
- INCENP | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs61744797, COSV53922026; called by muse, mutect2, varscan2
- KCNJ5 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57972084; called by muse, mutect2, varscan2
- KDM6A | c.2355G>A p.M785I | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV65037916, COSV65047508; called by muse, mutect2, varscan2
- KIAA1549L | c.2289G>A p.M763I (on ENST00000321505; = p.M1060I on NM_012194.3) | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs367876874; called by muse, mutect2, varscan2
- KRT35 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV55844836; called by muse, mutect2, varscan2
- LGR5 | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs765873009, COSV57005036; called by muse, mutect2, varscan2
- LRRC4C | c.1384A>G p.M462V | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53440692; called by muse, mutect2, varscan2
- MAGEC2 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs201326446, COSV55999913, COSV56001984; called by muse, mutect2, varscan2
- MAP3K19 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs372912449; called by muse, mutect2, varscan2
- MOV10L1 | c.2701G>A p.G901R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53181190; called by muse, mutect2, varscan2
- MSR1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs764485699, COSV100027194, COSV50542872; called by muse, mutect2, varscan2
- MUC16 | c.34503G>C p.M11501I | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV67448587, COSV67501632; called by muse, mutect2, varscan2
- MUC16 | c.8956A>T p.R2986* | Nonsense Mutation (SNP) | VAF 68/244 reads (28%) | catalogued as COSV67501639; called by muse, mutect2, varscan2
- MYH13 | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as rs752113103, COSV52846288; called by muse, mutect2, varscan2
- MYO6 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV64122041; called by muse, mutect2, varscan2
- NEGR1 | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0.026); catalogued as rs774726386, COSV60879618; called by muse, mutect2, varscan2
- OR6F1 | c.665T>G p.I222S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57469813; called by muse, mutect2
- PCDH17 | c.3241C>G p.P1081A | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV64980609; called by muse, mutect2, varscan2
- PCDHGA2 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as COSV54053457; called by muse, mutect2, varscan2
- PDE10A | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs769292110, COSV63091632, COSV63101499; called by muse, mutect2, varscan2
- PHKG1 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV51919456; called by muse, mutect2, varscan2
- PIK3R5 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs370964753; called by muse, mutect2
- PRDM14 | c.1565G>T p.C522F | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52575888; called by muse, mutect2, varscan2
- PTGS2 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 49/136 reads (36%) | catalogued as COSV66570274; called by muse, mutect2, varscan2
- PTPRF | c.5364+1G>A p.X1788_splice | Splice Site (SNP) | VAF 49/132 reads (37%) | catalogued as COSV63449871; called by muse, mutect2, varscan2
- R3HDML | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs375615013; called by muse, varscan2
- RBM19 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as rs748653257, COSV55700152; called by muse, mutect2, varscan2
- RNF17 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV55053714, COSV99694410; called by muse, mutect2, varscan2
- RTP1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56617942, COSV56618257; called by muse, mutect2, varscan2
- RUBCNL | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs372724179; called by muse, mutect2, varscan2
- SDK1 | c.2273C>A p.T758K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67392225; called by muse, mutect2, varscan2
- SEMA5B | c.2110G>A p.V704M | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52110662, COSV99531700; called by muse, mutect2, varscan2
- SHISA2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs779132447, COSV60112222; called by muse, mutect2, varscan2
- SIM1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as rs1371947558, COSV53497861; called by muse, mutect2, varscan2
- SLC6A19 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs748703513, COSV58669394; called by muse, mutect2, varscan2
- SPINT1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs145193299; called by muse, mutect2, varscan2
- SYNE1 | c.20647C>T p.R6883C (on ENST00000367255 / NM_182961.4; = p.R6812C on NM_033071.3) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs746823107, COSV54957826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TET1 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV65390281; called by muse, mutect2, varscan2
- TRABD2A | c.1108C>T p.R370W (on ENST00000409520 / NM_001277053.2; = p.R321W on NM_001080824.3) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs754667701, COSV52855165; called by muse, mutect2, varscan2
- TRIM21 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV54343465; called by muse, mutect2, varscan2
- TRPV6 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200085165, COSV100844258, COSV63894138; called by muse, mutect2, varscan2
- USP7 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs763719614, COSV61212628, COSV61218242; called by muse, mutect2, varscan2
- ZNF91 | c.925del p.A310Lfs*61 | Frame Shift Del (DEL) | VAF 35/150 reads (23%) | catalogued as COSV100323747; called by mutect2, pindel, varscan2
- CBWD6 | c.901A>G p.K301E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by mutect2, varscan2
- SLC35B2 | c.884del p.Y295Lfs*8 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3959C>A p.P1320H | Missense Mutation (SNP) | VAF 164/193 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- AHRR | c.816C>T p.P272= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs761611426, COSV57092023; called by muse, mutect2, varscan2
- ASCC3 | c.4647T>C p.I1549= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV64982271; called by muse, mutect2, varscan2
- CCDC136 | c.834G>A p.T278= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as rs758606123, COSV52803078; called by muse, mutect2, varscan2
- CNOT1 | c.2925G>A p.L975= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55323318; called by muse, mutect2, varscan2
- COL5A1 | c.4785C>T p.D1595= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs149981025; ClinVar: likely benign; called by muse, mutect2, varscan2
- DACH1 | c.1344A>G p.A448= (on ENST00000619232 / NM_001366712.1; = p.A396= on NM_080759.6) | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV57522900; called by muse, mutect2, varscan2
- ERCC4 | c.1260G>A p.L420= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV61311843; called by muse, mutect2, varscan2
- FAM237A | c.384G>A p.A128= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs376138541, COSV101405557; called by muse, mutect2, varscan2
- GASK1B | c.1164A>G p.R388= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV56712608; called by muse, mutect2, varscan2
- GRIK3 | c.138C>T p.D46= | Silent (SNP) | VAF 93/222 reads (42%) | catalogued as rs150456185; called by muse, mutect2, varscan2
- HDGF | c.486G>A p.L162= | Silent (SNP) | VAF 81/179 reads (45%) | catalogued as COSV61978264; called by muse, mutect2, varscan2
- HFM1 | c.3627G>A p.E1209= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV54039152; called by muse, mutect2, varscan2
- IGKV1-6 | c.45C>T p.L15= | Silent (SNP) | VAF 105/262 reads (40%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1131C>T p.D377= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs371543581, COSV59098837; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCND2 | c.345C>T p.Y115= | Silent (SNP) | VAF 88/318 reads (28%) | catalogued as COSV58581461; called by muse, mutect2, varscan2
- MINDY4 | c.861C>T p.A287= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV54679326; called by muse, mutect2, varscan2
- OR14K1 | c.882C>T p.D294= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs756111410, COSV99314940; called by muse, mutect2, varscan2
- OR51G1 | c.816C>T p.R272= | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as rs372747926, COSV58969349; called by muse, mutect2, varscan2
- PCDHB7 | c.1659C>T p.D553= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV50829918; called by muse, mutect2, varscan2
- SCUBE1 | c.2775G>A p.G925= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV62617184; called by muse, mutect2, varscan2
- SDK1 | c.4587G>A p.S1529= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1007875661, COSV67368894; called by muse, mutect2, varscan2
- SLCO4C1 | c.876C>T p.Y292= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV60520854; called by muse, mutect2, varscan2
- TSPEAR | c.1884G>A p.A628= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs782562949, COSV59975864; called by muse, mutect2, varscan2
- ZNF280B | c.75C>T p.D25= | Silent (SNP) | VAF 60/103 reads (58%) | catalogued as rs906514615, COSV64529821; called by muse, mutect2, varscan2
- CALCR | c.51+2978C>T | Intron (SNP) | VAF 54/187 reads (29%) | catalogued as rs774519762, COSV64005791, COSV64008954; called by muse, mutect2, varscan2
